Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3949, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3949-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with an ulcerated colon carcinoma characterized histologically as a poorly differentiated, partially mucinous adenocarcinoma of the colorectal type, located 0.5 cm aborally to Bauhin's valve and encircling the intestinal wall at a length of 5 cm. Invasive spreading of the tumor within all intestinal wall layers up to the bordering mesocolic fatty tissue and the level of the subserosa.

Oral and aboral resection margins are tumor-free.

Three of nineteen lymph nodes display metastasis of the colon carcinoma, not extending across the capsules.

Stage of tumor is therefore: pT3, pN1 (3/19) L0 V0; G3 R0

Source: NCI Genomic Data Commons file 5ea5d9a9-5266-4a70-a974-bf9f4751493b (TCGA-AA-3949.09FA9D57-DD74-4902-A007-EC77402DBD0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).